Surgical pathology report (de-identified scan), TCGA case TCGA-55-6642, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6642-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name :Surgical Report

[REDACTED]
SEE REPORT:

[REDACTED] SURGICAL PATHOLOGY REPORT [REDACTED]

==== SPECIMEN DESCRIPTION: =====

- A. PORTION OF RIGHT LOWER LOBE OF LUNG, APC
- B. SUBCARINAL LYMPH NODE
- C. RIGHT LOWER LOBE OF LUNG
- D. INFERIOR PULMONARY LIGAMENT LYMPH NODE
- E. HILAR LYMPH NODE

==== PRE-OPERATIVE DIAGNOSIS: =====

Right lower lobe of lung mass

==== POST-OPERATIVE DIAGNOSIS: =====

Same, pending pathology

==== CLINICAL INFORMATION: =====

Right lower lobe of lung mass

==== INTRAOPERATIVE CONSULTATION: =====

APC DIAGNOSIS: "Adenocarcinoma (tissue submitted for genomics study)" by Dr.

==== GROSS DESCRIPTION: =====

A. Received in formalin is a wedge of lung, measuring 8.0 x 4.0 x 3.0 cm. There is a staple line, measuring 8.5 cm. The pleural surface is focally hemorrhagic, congested, and moderately anthracotic. In addition, the pleura is retracted adjacent to the staple line, measuring 2.5 cm in greatest dimensions. The pleural surface is inked black and the staple line margin is inked blue. On sectioning, a poorly circumscribed tan-gray tumor mass, measuring 3.5 x 3.0 x 1.5 cm is identified. The tumor mass grossly abuts the pleural surface and comes to within 0.1 cm of the staple line margin. The cut surface of the mass is hemorrhagic, gritty, and focally friable. The uninvolved portion of lung is tan-pink and spongy. Representative sections are submitted in four cassettes as follows: cassette 1 - tumor mass, pleural surface, and staple line margin; cassette 2 - tumor mass and pleural surface; cassette 3 - tumor mass and staple line margin; cassette 4 - uninvolved lung. APC. Received in formalin is an irregular portion of tan-gray soft tissue, measuring 2.2 x 1.0 x 0.2 cm. Its cut surface shows a poorly circumscribed tan-gray area, measuring 1.2 x 1.0 x 0.2 cm. The specimen is entirely submitted in one cassette.

B. Received in formalin are multiple irregular pieces of tan-pink fibroconnective tissue with adjoining lymph nodes, measuring 2.5 x 2.0 x 0.5 cm in aggregate. Upon palpation, two tan-gray nodules, measuring 0.2 cm and

[page 2 of 4]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient [REDACTED]

MRN [REDACTED]

Date of Service [REDACTED]

Performing Facility [REDACTED]

Ordering Provider [REDACTED]

Result Provider [REDACTED]

Report Name

:Surgical Report

0.8 cm in greatest dimension, are found. The nodules are entirely submitted in one cassette.

C. Received in formalin is a 230 gram lobe of lung, measuring 18.0 x 14.0 x 4.5 cm in overall dimensions. There are multiple staple lines adjacent to the hilum, ranging from 3.0 cm to 10.0 cm in greatest dimension. The pleural surface is tan-pink, moderately anthracotic and diffusely hemorrhagic and congested adjacent to the hilum. There is a portion of bronchus at the hilum, measuring 0.6 cm in length x 2.5 cm in diameter. Also there is a portion of vessel, measuring 0.4 cm in length x 1.0 cm in diameter. The vascular, bronchial, and staple line margins are inked blue and the pleural surface is inked black. On sectioning, a circumscribed tan-gray tumor mass, measuring 0.8 x 0.6 x 0.5 cm is identified. The mass comes to within 2.5 cm from the pleural surface, 6.0 cm from the bronchial resection margin, and 5.5 cm from the closest staple line margin. The cut surface is gray and mucoid. In addition, directly adjacent to the hilum, approximately 1.0 cm from the bronchial margin, and 0.1 cm from the closest staple line margin is a very poorly circumscribed tan-orange lesion, measuring 2.0 x 1.5 x 1.0 cm. The lesion comes to within 1.0 cm from the pleural surface. The remainder of the lung parenchyma is spongy and congested and shows a bulla located at the upper pole, measuring 2.0 x 2.0 x 1.0 cm. A single anthracotic lymph node, measuring 0.5 cm in greatest dimension, is identified at the hilum. Representative sections are submitted in eight cassettes as follows: cassette 1 - bronchial margin; cassette 2 - vascular margin and lymph node at the hilum; cassette 3 - small tumor; cassette 4 - pleural surface closest to the tumor; cassette 5 - orange lesion adjacent to hilum; cassette 6 - orange lesion and closest staple line margin; cassette 7 - bulla; cassette 8 - lung parenchyma.

D. Received in formalin is an irregular portion of tan-pink soft tissue, measuring 1.5 x 0.7 x 0.4 cm. The specimen contains multiple staples. The staples are removed and no discrete lymph node is found. The specimen is entirely submitted in one cassette.

E. Received in formalin is a dark brown to black ovoid nodule, measuring 1.2 x 0.5 x 0.3 cm. The specimen is serially sectioned to reveal an anthracotic cut surface. The specimen is entirely submitted in one cassette.

[REDACTED]

==== MICROSCOPIC DESCRIPTION: =====

A & APC. Five slides are examined. Sections of lung include a tumor mass composed of complex anastomosing glands and papillae within fibrous stroma. The tumor cells have abundant eosinophilic to clear cytoplasm with polygonal cytoplasmic borders. The nuclei are enlarged and ovoid to irregular, with thickened nuclear membranes, coarsely granular chromatin and prominent nucleoli. Scattered mitoses are present. Tumor focally extends into the visceral pleura, forming a fibrotic nodule on the pleural surface, composed of

[page 3 of 4]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

:Surgical Report

more solid nests of cells within fibrotic stroma.

B. One slide is examined. These are sections of lymph node characterized by moderate sinus histiocytosis and anthracosis. There is no evidence of involvement by tumor.

C. Eight slides are examined. Sections of lung include residual tumor (slides 5 and 6), composed of abnormal glands. There is surrounding pneumonitis with aggregated foamy histiocytes present within alveoli, associated with interstitial infiltration by inflammatory cells, including lymphocytes, plasma cells and eosinophils. Sections of the second-described mass (block C3) reveal a circumscribed, but non-encapsulated, nodular mass, composed of a monotonous population of cells having ovoid to spindle-shaped nuclei, arranged in a nested/organoid pattern. The cells have bland chromatin with inconspicuous nucleoli. Mitotic figures are not readily identified. The grossly-described bullous area is characterized by irregular disruption of the subpleural alveolar architecture, associated with irregular fibrous thickening of the pleura, which is infiltrated by chronic inflammatory cells, including lymphocytes and plasma cells, forming occasional loose aggregates. Clusters of pigmented histiocytes are present within the dilated alveolar spaces. Random sections of lung reveal mild patchy dilation of alveoli, most notably within the peripheral portions of the parenchyma. No other tumor is identified. Sections of the bronchial margin are lined by ciliated, pseudostratified columnar epithelium with areas of squamous metaplasia. The vascular margin of resection is uninvolved by tumor. A peribronchial lymph node is characterized by sinus histiocytosis and anthracosis. There is no morphologic evidence of involvement by tumor.

D. One slide is examined, including the entirely submitted specimen. These are sections of a biopsy portion of lung, composed of benign alveolar parenchyma. There is adherent fibrofatty tissue, consistent with parietal pleura. There is no evidence of involvement by tumor. No lymph node is identified.

E. One slide is examined. These are sections of clotted blood and organizing fibrin. A few clusters of mildly reactive mesothelial cells are focally present within the clot, occasionally forming gland-like structures. No lymph node is identified within the entirely submitted specimen.

==== SPECIAL STAINS: =====

A section of tumor (block A1) is stained by the immunoperoxidase method for thyroid transcription factor-1 (TTF-1). The tumor cells reveal weak to moderate intranuclear positivity, consistent with lung primary. A section of block E is also stained for TTF-1. The clusters of cells morphologically interpreted as mesothelial cells, are negative by this stain. Also stained is a section of the spindle cell tumor, seen on block C3, within the completion lobectomy specimen. The cells comprising the lesion are strongly and

[page 4 of 4]
Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name :Surgical Report

diffusely positive for synaptophysin with moderate positivity for chromogranin, consistent with the morphologic interpretation of spindle cell carcinoid tumor. The corresponding controls stain appropriately.

===== FINAL DIAGNOSIS: =====

- A & APC. RIGHT LUNG, LOWER LOBE, WEDGE BIOPSY:
1. HISTOLOGIC TYPE: ADENOCARCINOMA
2. HISTOLOGIC GRADE: GRADE II
3. PRIMARY TUMOR: pT2 - SEE COMMENT
4. REGIONAL LYMPH NODES: pN0 (NO REGIONAL LYMPH NODE METASTASIS - SEE PARTS B AND C)
5. DISTANT METASTASIS: pMX (CANNOT BE ASSESSED)
6. MARGINS: TUMOR PRESENT AT VISCERAL PLEURAL SURFACE
7. VENOUS (LARGE VESSEL) INVASION: NOT IDENTIFIED
8. ARTERIAL (LARGE VESSEL) INVASION: NOT IDENTIFIED
- B. LYMPH NODE (SUBCARINAL), EXCISION: NEGATIVE FOR TUMOR
- C. RIGHT LUNG, LOWER LOBE, COMPLETION LOBECTOMY:
1. RESIDUAL ADENOCARCINOMA, WITH SURROUNDING OBSTRUCTIVE/LIPOID PNEUMONIA
2. BRONCHIAL MARGIN UNINVOLVED
3. ONE PERIBRONCHIAL LYMPH NODE NEGATIVE FOR TUMOR
4. SPINDLE CELL CARCINOID TUMOR (8MM)
5. SUBPLEURAL BULLA
- D. INFERIOR PULMONARY LIGAMENT, BIOPSY: BENIGN LUNG PARENCHYMA AND ADHERENT FIBROFATTY TISSUE, CONSISTENT WITH PARIETAL PLEURA; NO EVIDENCE OF INVOLVEMENT BY TUMOR
- E. LYMPH NODE (HILAR), BIOPSY: CLOTTED BLOOD AND FIBRIN WITH REACTIVE MESOTHELIAL CELLS, NEGATIVE FOR TUMOR

COMMENT: The tumor within the wedge resection specimen grossly measures 3.5 cm in greatest dimension, with direct extension into the visceral pleura. A small amount of residual tumor is present within the completion lobectomy specimen.

A-MALIGNANT

[REDACTED]

DATE AND TIME OF [REDACTED]

Source: NCI Genomic Data Commons file 96908e1f-fc46-4b58-9c16-c657af74d121 (TCGA-55-6642.5D390C9F-0F12-4ED2-A7EC-D9E7C8F05320.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).